Somatic mutation profile of tumor specimen TCGA-HC-A6AL-01A (aliquot TCGA-HC-A6AL-01A-11D-A30E-08) from TCGA case TCGA-HC-A6AL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.7 years (23,618 days).
Specimen TCGA-HC-A6AL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db39de94-07fb-4a6f-b0de-f9dbbe2264a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A6AL-10A (Blood Derived Normal), aliquot TCGA-HC-A6AL-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f60d2d34-e9e3-4789-a533-fd8dfd07a050

The open-access MAF lists 48 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 12, Frame Shift Del 2, Splice Site 1, Nonsense Mutation 1, Nonstop Mutation 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC104452.1 | c.1392G>C p.Q464H | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated, low confidence (0.53); PolyPhen possibly damaging (0.868); catalogued as rs972972652, COSV55534282; called by muse, mutect2, varscan2
- ADAM21 | c.460T>C p.F154L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs1350883138, COSV50802498; called by muse, varscan2
- ADGRG4 | c.2683A>G p.T895A | Missense Mutation (SNP) | VAF 75/110 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV54963258; called by muse, mutect2, varscan2
- C1orf159 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.715); catalogued as rs770490055, COSV53881003; called by muse, mutect2, varscan2
- CCKAR | c.661C>G p.P221A | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201996688, COSV55161073, COSV55163077; called by muse, mutect2, varscan2
- CES1 | c.946C>A p.Q316K | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV62089120; called by muse, mutect2, varscan2
- CNOT3 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 99/320 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55360792; called by muse, mutect2, varscan2
- COPB2 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV60350840; called by muse, mutect2
- DISP3 | c.1711A>G p.T571A | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53834219; called by muse, mutect2, varscan2
- DPP10 | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV59709291; called by muse, mutect2, varscan2
- GRIN2C | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53116489; called by muse, mutect2
- KRBA1 | c.2728C>T p.R910W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs760290386, COSV55443237; called by muse, varscan2
- LMTK2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV52001096; called by muse, mutect2, varscan2
- LRP1B | c.9626T>C p.V3209A | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV67256008; called by muse, mutect2
- MED12 | c.3430G>C p.E1144Q | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV61350831; called by muse, mutect2, varscan2
- MROH2B | c.1635G>T p.L545F | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1447131866, COSV68187550; called by muse, mutect2, varscan2
- NOTUM | c.802T>C p.F268L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.869); catalogued as COSV68826462; called by muse, mutect2, varscan2
- OR3A3 | c.910A>C p.T304P | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV52167270, COSV52168149; called by muse, mutect2, varscan2
- PES1 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58829353; called by muse, mutect2, varscan2
- PLAA | c.1970T>C p.L657P | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68305391; called by muse, mutect2, varscan2
- PLVAP | c.120C>G p.I40M | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53086773; called by muse, mutect2, varscan2
- PRKD1 | c.638G>C p.S213T | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV59579150; called by muse, mutect2, varscan2
- PTEN | c.454del p.L152* | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | catalogued as CM132266, COSV64294195, COSV64297256; called by mutect2, pindel, varscan2
- RTP1 | c.705C>A p.N235K | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as rs766301180, COSV56619164; called by muse, mutect2, varscan2
- SAMD9L | c.1717G>A p.G573R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59083932; called by muse, mutect2, varscan2
- SBSN | c.1696G>A p.A566T (on ENST00000452271 / NM_001166034.2; = p.A223T on NM_198538.4) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV71733314; called by muse, mutect2, varscan2
- TENM3 | c.4840A>T p.S1614C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV69315197, COSV69315942; called by muse, mutect2, varscan2
- TESMIN | c.1116C>A p.C372* | Nonsense Mutation (SNP) | VAF 89/297 reads (30%) | catalogued as COSV54833164; called by muse, mutect2, varscan2
- TIE1 | c.1506G>T p.E502D | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV100992148, COSV65250798; called by muse, mutect2, varscan2
- UGDH | c.1238T>C p.I413T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV57099325; called by muse, mutect2
- VPS41 | c.1186-2A>G p.X396_splice | Splice Site (SNP) | VAF 10/73 reads (14%) | catalogued as COSV59651707; called by muse, mutect2, varscan2
- ZNF140 | c.1374A>C p.*458Cext*39 | Nonstop Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV60579740; called by muse, mutect2, varscan2
- ZNF692 | c.516G>C p.R172S | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV60659967; called by muse, mutect2, varscan2
- CBLN1 | c.536del p.G179Afs*34 | Frame Shift Del (DEL) | VAF 14/125 reads (11%) | called by mutect2, pindel, varscan2
- GRWD1 | c.262_266dup p.L89Ffs*17 | Frame Shift Ins (INS) | VAF 25/86 reads (29%) | called by mutect2, varscan2
- ADGRE3 | c.93C>T p.C31= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV53733298; called by muse, mutect2, varscan2
- ERO1B | c.544C>T p.L182= | Silent (SNP) | VAF 31/173 reads (18%) | catalogued as COSV59243384; called by muse, mutect2, varscan2
- FLT1 | c.2307G>A p.A769= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs142392658; called by muse, mutect2, varscan2
- OR3A3 | c.909T>C p.N303= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV52168139; called by muse, mutect2, varscan2
- OR4C6 | c.729G>T p.T243= | Silent (SNP) | VAF 78/203 reads (38%) | catalogued as rs528437339, COSV58602689, COSV58605559; called by muse, mutect2, varscan2
- PCDHA6 | c.1509G>A p.A503= | Silent (SNP) | VAF 26/170 reads (15%) | catalogued as rs782636374, COSV100971740, COSV65343482; called by muse, mutect2, varscan2
- PLEKHG3 | c.210C>T p.N70= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs551678656, COSV55982318; called by muse, mutect2, varscan2
- PLPPR2 | c.639C>T p.C213= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs1366791038, COSV52261624; called by muse, mutect2, varscan2
- POM121 | c.1200T>G p.A400= (on ENST00000434423; = p.A135= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/322 reads (22%) | catalogued as COSV57521464; called by muse, mutect2, varscan2
- SCN7A | c.2934C>A p.I978= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs1263059484, COSV101313158, COSV69273637; called by muse, mutect2
- TAB1 | c.1317G>A p.P439= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as rs763081696, COSV53372574, COSV99336175; called by muse, mutect2
- ZNF641 | c.72G>A p.G24= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV56391178; called by muse, mutect2, varscan2
- SRSF1 | c.-18_-2del | 5'UTR (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel
